Somatic mutation profile of tumor specimen TARGET-10-PANZBY-03A (aliquot TARGET-10-PANZBY-03A-01D) from TARGET case TARGET-10-PANZBY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,044 days).
Specimen TARGET-10-PANZBY-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ac8f00d-dd3b-4d13-b5ad-76be67a35718.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANZBY-14A (Bone Marrow Normal), aliquot TARGET-10-PANZBY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61a8380d-41b3-426e-9936-d195dfbf3964

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 19/32 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SYNE2 | c.18639C>A p.S6213R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV59958268; called by muse, mutect2
- TFAP4 | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.827); catalogued as COSV99200048; called by muse, mutect2, varscan2
- CHD9 | c.6320C>A p.A2107D | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- GK2 | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- PGBD2 | c.1518C>A p.C506* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- EPPK1 | c.4131G>A p.A1377= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs370174488; called by muse, mutect2, varscan2
- PCDHA9 | c.1722C>T p.D574= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs781838621, COSV65327786; called by muse, mutect2, varscan2
- PPP1R9A | c.*1C>A | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
